Somatic mutation profile of tumor specimen TARGET-10-PARTAY-09A (aliquot TARGET-10-PARTAY-09A-01D) from TARGET case TARGET-10-PARTAY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,568 days).
Specimen TARGET-10-PARTAY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5875bb4e-057e-4761-8f80-eac17ef61fcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTAY-10A (Blood Derived Normal), aliquot TARGET-10-PARTAY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf9a076-2784-4e58-b5c2-265cbab99b15

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as rs543757679, COSV59371141; called by muse, mutect2, varscan2
- DNAH9 | c.8138G>A p.R2713Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs771083100, COSV99306316; called by muse, mutect2, varscan2
- MAGED1 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs782664441, COSV58517102; called by muse, mutect2, varscan2
- SPATA17 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 52/101 reads (51%) | catalogued as rs756118007; called by muse, mutect2, varscan2
- TGM2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs146118608; called by muse, mutect2, varscan2
- TTN | c.23068C>T p.R7690* (on ENST00000591111; = p.R6763* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as rs794727941, COSV59903910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR33 | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.09); catalogued as rs1413201012; called by muse, mutect2, varscan2
- FASTKD1 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ZC3H4 | c.483dup p.Y162Ifs*38 | Frame Shift Ins (INS) | VAF 25/63 reads (40%) | called by mutect2, pindel*, varscan2
- IGHV1-2 | c.345T>C p.C115= | Silent (SNP) | VAF 21/24 reads (88%) | called by mutect2, varscan2
- IGHV1-45 | chr14:106506990 ACTGTGT>CTCCG | Silent (DEL) | VAF 53/62 reads (85%) | called by pindel, varscan2*
- PIEZO2 | c.588G>A p.T196= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as rs200920431, COSV100128579; called by muse, mutect2
- RBL1 | c.264C>T p.T88= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as rs1365548079; called by muse, mutect2
- RBPJ | c.60-23836G>T | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
